Somatic mutation profile of tumor specimen TCGA-XU-A92Y-01A (aliquot TCGA-XU-A92Y-01A-11D-A423-09) from TCGA case TCGA-XU-A92Y, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Thymoma, type B3, malignant; Tissue or organ of origin: Anterior mediastinum; Age at diagnosis: 71.2 years (26,021 days).
Specimen TCGA-XU-A92Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7966fe92-53f4-498b-8772-fd4ad4f5d549.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XU-A92Y-10A (Blood Derived Normal), aliquot TCGA-XU-A92Y-10A-01D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/16d74d20-42f1-4df0-ba4c-9e6f48d95d03

The open-access MAF lists 9 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 7, Silent 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNKSR3 | c.289A>G p.N97D | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.233); catalogued as COSV72161862; called by muse, mutect2, varscan2
- COL11A1 | c.611C>T p.T204M | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs199595073; called by muse, mutect2, varscan2
- EDN2 | c.311C>A p.P104H | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV101006313; called by muse, mutect2
- FAM111B | c.1760T>C p.I587T | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.044); catalogued as rs765228450, COSV59112063; called by muse, mutect2, varscan2
- NRAP | c.3081G>A p.T1027= (on ENST00000359988 / NM_001322945.2; = p.T992= on NM_006175.4) | Splice Region (SNP) | VAF 10/69 reads (14%) | catalogued as rs372300454; called by muse, mutect2, varscan2
- PKLR | c.508G>A p.G170S | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.066); catalogued as rs779196057; called by muse, mutect2, varscan2
- CCDC43 | c.500A>G p.N167S | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LGALS3BP | c.391C>G p.H131D | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PEG10 | c.948G>A p.S316= (on ENST00000482108 / NM_001040152.2; = p.S350= on NM_015068.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/77 reads (9%) | catalogued as COSV71788466; called by muse, mutect2
